Somatic mutation profile of tumor specimen TCGA-D5-6924-01A (aliquot TCGA-D5-6924-01A-11D-1924-10) from TCGA case TCGA-D5-6924, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 68.3 years (24,964 days).
Specimen TCGA-D5-6924-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2768b3c2-4919-4652-8e55-6e9109223dd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6924-10A (Blood Derived Normal), aliquot TCGA-D5-6924-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72e397ad-da16-442d-875c-f8df0c534706

The open-access MAF lists 146 somatic variants for this specimen: 113 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 31, Nonsense Mutation 9, In Frame Del 2, Splice Region 2, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 44/126 reads (35%) | hotspot (GDC flag); catalogued as rs137854580, CM930023, COSV57322064; ClinVar: pathogenic; called by muse, varscan2
- APC | c.3880C>T p.Q1294* | Nonsense Mutation (SNP) | VAF 25/105 reads (24%) | hotspot (GDC flag); catalogued as rs1554085373, CD058148, CD132712, CM930027, COSV57323524; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 30/37 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC244197.3 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 107/131 reads (82%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as rs781916566, COSV61711863; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS16 | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs539873933, COSV56983275, COSV99941580; called by muse, mutect2
- ADAMTS7 | c.2275G>A p.G759R | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs778784747, COSV101183241, COSV66306895; called by muse, mutect2, varscan2
- ADCY3 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as COSV53166860; called by muse, mutect2, varscan2
- AGAP4 | c.1847T>C p.L616P | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101432595; called by mutect2, varscan2
- AKAP13 | c.4154C>G p.T1385S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV63454690; called by muse, mutect2, varscan2
- ARHGAP35 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as rs1324543011, COSV68330725; called by muse, mutect2, varscan2
- ARNTL | c.827G>A p.R276Q (on ENST00000403290 / NM_001297719.2; = p.R275Q on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.038); catalogued as rs1254604798, COSV62986299; called by muse, mutect2, varscan2
- ATF7IP | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1321285227, COSV53769872; called by muse, mutect2, varscan2
- ATP1A2 | c.2270C>T p.T757M | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1333695385, COSV63403502; called by muse, mutect2, varscan2
- ATP8A2 | c.2764G>A p.A922T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs190982690; called by muse, mutect2, varscan2
- BRD2 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.695); catalogued as COSV66373056; called by muse, mutect2, varscan2
- BSN | c.6992T>A p.L2331Q | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.278); catalogued as COSV56516734; called by muse, mutect2, varscan2
- CACUL1 | c.716A>T p.K239M | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60994021; called by muse, mutect2, varscan2
- CBLIF | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1257466616, COSV57238703; called by muse, mutect2, varscan2
- CCDC74B | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs372517815; called by muse, mutect2, varscan2
- CNTNAP4 | c.1745G>T p.G582V | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56676882; called by muse, mutect2, varscan2
- COL11A1 | c.4033G>T p.G1345C | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62181304; called by muse, mutect2, varscan2
- COL6A5 | c.7381C>T p.P2461S (on ENST00000312481; = p.P2457S on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55199448; called by muse, mutect2, varscan2
- COP1 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV58166262; called by muse, mutect2, varscan2
- COPB2 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60812404; called by muse, mutect2, varscan2
- CROCC | c.3293A>G p.D1098G | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV65011684; called by muse, mutect2, varscan2
- CSMD2 | c.7229A>G p.E2410G | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.925); catalogued as COSV53906138; called by muse, mutect2, varscan2
- DNMT3B | c.1716G>C p.R572S | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52417714; called by muse, mutect2, varscan2
- DUXA | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs200454436; called by muse, mutect2, varscan2
- DYNAP | c.437T>A p.I146N (on ENST00000321600; = p.I120N on NM_173629.3) | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV58666314; called by muse, mutect2, varscan2
- EIF3F | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as rs904105385, COSV59142069; called by muse, mutect2, varscan2
- ERBB4 | c.3258C>A p.S1086R | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100722820; called by muse, mutect2
- FADS3 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as rs1317789717, COSV53878118; called by muse, mutect2, varscan2
- FAM78B | c.133A>T p.K45* | Nonsense Mutation (SNP) | VAF 17/114 reads (15%) | catalogued as COSV57976747; called by muse, mutect2, varscan2
- FBXL20 | c.629A>G p.D210G | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV52898348; called by muse, mutect2, varscan2
- FBXO11 | c.1466A>G p.N489S (on ENST00000403359 / NM_001190274.2; = p.N405S on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV57018771; called by muse, mutect2, varscan2
- FCRL5 | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs775662679, COSV62513776; called by muse, mutect2, varscan2
- FGF17 | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV63925503; called by muse, mutect2, varscan2
- FOXI1 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as rs775106921, COSV60388489; called by muse, mutect2, varscan2
- FOXO1 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 95/148 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV65426497; called by muse, mutect2, varscan2
- FRYL | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV99975537; called by muse, mutect2, varscan2
- GGT7 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.654); catalogued as rs201808310, COSV60540599; called by muse, mutect2, varscan2
- GPC2 | c.1311G>A p.R437= | Splice Region (SNP) | VAF 19/42 reads (45%) | catalogued as rs1349736188, COSV99444306; called by muse, mutect2, varscan2
- GPR137B | c.1115G>A p.W372* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as COSV63992576; called by muse, mutect2, varscan2
- GPR31 | c.17G>T p.C6F | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs201491639, COSV64761379; called by muse, mutect2, varscan2
- GRIA4 | c.1742G>C p.G581A | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.142); catalogued as COSV56892996, COSV56907493; called by muse, mutect2, varscan2
- GRIK2 | c.1852G>T p.A618S | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV100024036, COSV59730960; called by muse, mutect2, varscan2
- GRM6 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs766682788, COSV99179430; called by muse, mutect2, varscan2
- HDHD3 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs528728306, COSV53057004; called by muse, mutect2, varscan2
- HERC2 | c.9440T>A p.V3147D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV55320193; called by muse, mutect2, varscan2
- HTR5A | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.332); catalogued as rs147688293, COSV55282547; called by muse, mutect2, varscan2
- IKZF4 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56267956; called by muse, mutect2, varscan2
- ITPR3 | c.1927A>T p.I643F | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as COSV100966860; called by muse, mutect2, varscan2
- KLHL14 | c.1507G>C p.D503H | Missense Mutation (SNP) | VAF 75/133 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV63830724; called by muse, mutect2, varscan2
- LRP1 | c.7816G>A p.G2606S | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV54509179; called by muse, mutect2, varscan2
- LZTS1 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199863998, COSV56115761, COSV56117209, COSV99742813; called by muse, mutect2, varscan2
- MAL | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs749751444, COSV59431309; called by muse, mutect2, varscan2
- MAP1B | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.208); catalogued as COSV57097455; called by muse, mutect2, varscan2
- MKI67 | c.8317A>T p.T2773S | Missense Mutation (SNP) | VAF 74/288 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.743); catalogued as COSV64074082; called by muse, mutect2, varscan2
- MLLT10 | c.304C>G p.H102D | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV56994750; called by muse, mutect2, varscan2
- MRC2 | c.3596T>C p.V1199A | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.13); catalogued as COSV100315730; called by muse, mutect2
- MRGPRX3 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.92); catalogued as rs770342530, COSV66933999; called by muse, mutect2, varscan2
- MROH7 | c.1798T>A p.F600I | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV100272783; called by muse, mutect2, varscan2
- NCKAP1L | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.378); catalogued as COSV53206034, COSV99515384; called by muse, mutect2
- NCLN | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1263931597, COSV55741918; called by muse, mutect2, varscan2
- NDST4 | c.1458A>C p.K486N | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.029); catalogued as COSV99995299; called by muse, mutect2, varscan2
- NECAB3 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.217); catalogued as rs777446950, COSV55775777; called by muse, mutect2, varscan2
- NFAM1 | c.416_426del p.T139Kfs*95 | Frame Shift Del (DEL) | VAF 33/107 reads (31%) | catalogued as COSV61195060; called by mutect2, pindel, varscan2
- NFIL3 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 74/137 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.183); catalogued as rs780645794, COSV52683466; called by muse, mutect2, varscan2
- NIPBL | c.4903G>A p.E1635K | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV56961476; called by muse, mutect2
- NPAP1 | c.571T>G p.S191A | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as COSV100274692; called by muse, mutect2
- OPRPN | c.721C>G p.Q241E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.075); catalogued as COSV68192826; called by muse, mutect2, varscan2
- OR10R2 | c.427T>A p.Y143N | Missense Mutation (SNP) | VAF 83/311 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63768768; called by muse, mutect2, varscan2
- OR11H4 | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 85/164 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59560193; called by muse, mutect2, varscan2
- OR2L3 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100741904, COSV63455662; called by muse, mutect2, varscan2
- OR8B8 | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.394); catalogued as COSV60144411; called by muse, mutect2, varscan2
- PARD3B | c.3419C>T p.P1140L (on ENST00000406610 / NM_001302769.2; = p.P1071L on NM_057177.7) | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV100591978; called by muse, mutect2, varscan2
- PCDH15 | c.1677T>G p.N559K | Missense Mutation (SNP) | VAF 70/296 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV57298444; called by muse, mutect2, varscan2
- PCDHA6 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.603); catalogued as rs561019835, COSV65343652; called by muse, mutect2, varscan2
- PHF20 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV100179832; called by muse, mutect2
- PPFIBP1 | c.1631T>G p.L544* (on ENST00000318304 / NM_177444.3; = p.L527* on NM_003622.4) | Nonsense Mutation (SNP) | VAF 27/142 reads (19%) | catalogued as COSV57290463; called by muse, mutect2, varscan2
- PREX1 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs148948169; called by muse, mutect2, varscan2
- PTPRT | c.2195C>A p.S732Y | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV61968230, COSV61976818; called by muse, mutect2, varscan2
- RAB40B | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs749420184, COSV99483420; called by muse, mutect2, varscan2
- RCHY1 | c.292_294del p.K98del | In Frame Del (DEL) | VAF 32/106 reads (30%) | catalogued as rs756147426; called by pindel, varscan2
- SCN5A | c.3206C>T p.T1069M | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs199473187, CM055518, COSV61122207; ClinVar: likely benign / uncertain significance / not provided; called by muse, mutect2, varscan2
- SERPIND1 | c.311C>G p.T104R | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.075); catalogued as rs754910028, COSV53138390; called by muse, mutect2, varscan2
- SIN3A | c.1058T>A p.L353* | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | catalogued as COSV64582606; called by muse, mutect2, varscan2
- SMG7 | c.2743-1G>A p.X915_splice | Splice Site (SNP) | VAF 12/58 reads (21%) | catalogued as COSV61630836; called by muse, mutect2, varscan2
- SORT1 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 99/228 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.129); catalogued as rs552332611, COSV56665814; called by muse, mutect2, varscan2
- SRPK1 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV60412418; called by muse, mutect2, varscan2
- ST8SIA2 | c.159T>C p.N53= | Splice Region (SNP) | VAF 38/97 reads (39%) | catalogued as COSV51568866; called by muse, mutect2, varscan2
- SUN5 | c.245C>G p.T82S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.369); catalogued as rs1222743955, COSV62180911; called by muse, mutect2, varscan2
- SYNE1 | c.9807G>T p.K3269N (on ENST00000367255 / NM_182961.4; = p.K3276N on NM_033071.3) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99551516; called by muse, mutect2, varscan2
- TAAR8 | c.592G>T p.V198L | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as rs551481130, COSV51586133; called by muse, mutect2, varscan2
- TASOR2 | c.5774dup p.Y1925* | Nonsense Mutation (INS) | VAF 12/54 reads (22%) | catalogued as rs1308362486; called by mutect2, pindel, varscan2
- TBX20 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV68783409; called by muse, mutect2, varscan2
- TENT5D | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV57636262; called by muse, mutect2, varscan2
- TEPSIN | c.1319A>G p.E440G | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV56142506; called by muse, mutect2, varscan2
- TLE6 | c.622T>G p.S208A (on ENST00000246112 / NM_001143986.2; = p.S85A on NM_024760.3) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.085); catalogued as COSV55735319; called by muse, mutect2, varscan2
- TNIK | c.2105A>C p.Q702P | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV52680337; called by muse, mutect2, varscan2
- TNRC6B | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV57289495; called by muse, mutect2, varscan2
- TRIM55 | c.1199C>A p.P400Q | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.261); catalogued as COSV52545753, COSV52549303; called by muse, mutect2, varscan2
- TRPM1 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as rs750109963, CM158233, COSV56640995; called by muse, mutect2
- VPS50 | c.62G>T p.S21I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV52494484; called by muse, mutect2, varscan2
- WNT11 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs528803907, COSV59443658; called by muse, mutect2, varscan2
- ZEB2 | c.3173A>C p.D1058A | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV100354841; called by muse, mutect2, varscan2
- ZFHX4 | c.7819C>T p.R2607C | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309561230, COSV50480018, COSV50538350, COSV99265401; called by muse, mutect2, varscan2
- ZNF234 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as rs376364041; called by muse, mutect2, varscan2
- ZNF492 | c.566G>T p.R189I | Missense Mutation (SNP) | VAF 144/426 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.043); catalogued as COSV71761780; called by muse, mutect2
- ZNF831 | c.1845C>G p.F615L | Missense Mutation (SNP) | VAF 68/207 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64039513; called by muse, varscan2
- PAK3 | c.616del p.I206Sfs*56 (on ENST00000262836 / NM_001324328.2; = p.I191Sfs*56 on NM_002578.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 56/507 reads (11%) | called by mutect2, pindel, varscan2
- RGMB | c.1285dup p.T429Nfs*33 (on ENST00000513185 / NM_001366508.1; = p.T470Nfs*33 on NM_001012761.3 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 25/87 reads (29%) | called by mutect2, pindel, varscan2
- TMC3 | c.1859_1861del p.Y620del | In Frame Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- ABHD18 | c.1167T>A p.I389= (on ENST00000398965 / NM_001039717.2; = p.I296= on NM_025097.2 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV101180672; called by muse, mutect2, varscan2
- ADAMTS7 | c.153C>T p.V51= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV66306901; called by muse, mutect2, varscan2
- AVPR1A | c.177G>A p.A59= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs1392060259, COSV54546304; called by muse, mutect2, varscan2
- B3GALNT2 | c.624G>A p.K208= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs914123521, COSV58356222; called by muse, mutect2, varscan2
- CACNB1 | c.852C>G p.P284= | Silent (SNP) | VAF 44/130 reads (34%) | catalogued as COSV59998696; called by muse, mutect2, varscan2
- CCL14 | c.21C>A p.A7= | Silent (SNP) | VAF 60/159 reads (38%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.783C>T p.G261= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV62171779; called by muse, mutect2, varscan2
- COL24A1 | c.1236C>T p.I412= | Silent (SNP) | VAF 49/102 reads (48%) | catalogued as rs758826873, COSV65305286; called by muse, mutect2, varscan2
- DUSP9 | c.528C>T p.S176= | Silent (SNP) | VAF 69/87 reads (79%) | catalogued as rs1557036078, COSV61437920; called by muse, mutect2, varscan2
- FBXL18 | c.1623G>T p.L541= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs1261744059, COSV66107555; called by muse, mutect2, varscan2
- GABRG1 | c.117A>T p.A39= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV54953073; called by muse, mutect2, varscan2
- HOMER2 | c.435C>T p.N145= (on ENST00000304231 / NM_199330.3; = p.N134= on NM_004839.4) | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs760018246, COSV58484171; called by muse, mutect2, varscan2
- IGSF8 | c.792C>T p.D264= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs370022156; called by muse, mutect2, varscan2
- KIDINS220 | c.255C>T p.H85= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV56752659; called by muse, mutect2, varscan2
- LDHD | c.420C>G p.R140= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV55580713; called by muse, mutect2, varscan2
- LRBA | c.6501C>T p.F2167= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV63953963; called by muse, mutect2, varscan2
- MUC16 | c.28575C>A p.T9525= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs760191219, COSV67461953; called by muse, mutect2, varscan2
- NCAPH2 | c.696C>T p.S232= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV53218370; called by muse, mutect2
- PALD1 | c.1941C>T p.A647= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs757426491, COSV54972667; called by muse, mutect2, varscan2
- PCDH15 | c.903G>A p.T301= | Silent (SNP) | VAF 37/199 reads (19%) | catalogued as rs189227500; called by muse, mutect2, varscan2
- PCDHB5 | c.474G>A p.Q158= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as COSV50650226, COSV50661831; called by muse, mutect2, varscan2
- PCDHGA4 | c.711G>A p.A237= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV53935044; called by muse, mutect2, varscan2
- PTPA | c.6T>G p.A2= | Silent (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2
- SDR16C5 | c.771T>A p.A257= | Silent (SNP) | VAF 16/231 reads (7%) | catalogued as COSV100373754; called by muse, mutect2
- SDSL | c.705C>T p.A235= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as rs376935932; called by muse, mutect2, varscan2
- SEC31B | c.1680A>T p.T560= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV64844246; called by muse, mutect2, varscan2
- SLC8A1 | c.252C>T p.A84= | Silent (SNP) | VAF 50/153 reads (33%) | catalogued as COSV100244214, COSV100245579; called by muse, varscan2
- ST6GALNAC5 | c.1005G>T p.V335= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV59564484; called by muse, mutect2, varscan2
- TMEM130 | c.879C>T p.S293= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as rs781823887, COSV59558744; called by muse, mutect2, varscan2
- TSHZ2 | c.711G>A p.T237= | Silent (SNP) | VAF 12/161 reads (7%) | catalogued as COSV100295263; called by muse, mutect2
- ZNF347 | c.2331T>G p.T777= | Silent (SNP) | VAF 27/124 reads (22%) | catalogued as COSV61968480; called by muse, mutect2, varscan2
- PCDHGA6 | c.2424+23G>A | Intron (SNP) | VAF 27/82 reads (33%) | catalogued as rs200613052, COSV53935057; called by muse, mutect2, varscan2
- SFTA3 | n.941T>A | RNA (SNP) | VAF 45/87 reads (52%) | catalogued as COSV69489255; called by muse, mutect2, varscan2
